Somatic mutation profile of tumor specimen TCGA-HU-A4GD-01A (aliquot TCGA-HU-A4GD-01A-11D-A25D-08) from TCGA case TCGA-HU-A4GD, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 56.7 years (20,700 days).
Specimen TCGA-HU-A4GD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4e85d256-9ff7-4127-a36d-230f102a090b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HU-A4GD-10A (Blood Derived Normal), aliquot TCGA-HU-A4GD-10A-01D-A25E-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3741e367-24b4-4df9-b7c3-209f55412f48

The open-access MAF lists 88 somatic variants for this specimen: 65 protein-altering or splice-affecting, 19 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 56, Silent 19, Nonsense Mutation 3, Frame Shift Ins 2, In Frame Del 1, Intron 1, Splice Site 1, Frame Shift Del 1, Splice Region 1, RNA 1, 5'Flank 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.584T>A p.I195N | Missense Mutation (SNP) | VAF 22/38 reads (58%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs760043106, CM092575, COSV52661172, COSV52664264, COSV52684176, COSV52720899; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- AC011455.2 | c.787G>A p.G263R | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs141084630; called by muse, mutect2, varscan2
- ACTR1B | c.458C>T p.T153M | Missense Mutation (SNP) | VAF 28/155 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs201371421; called by muse, mutect2, varscan2
- AKAP12 | c.3340C>A p.Q1114K | Missense Mutation (SNP) | VAF 41/123 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.086); catalogued as COSV53570950; called by muse, mutect2, varscan2
- APLP2 | c.1964T>C p.I655T | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.39); PolyPhen benign (0.014); catalogued as COSV53839355; called by muse, mutect2, varscan2
- ARFIP2 | c.715C>T p.R239* | Nonsense Mutation (SNP) | VAF 46/65 reads (71%) | catalogued as rs976148032, COSV54446325; called by muse, mutect2, varscan2
- ARVCF | c.1033T>A p.S345T | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.22); PolyPhen benign (0.119); catalogued as COSV54265258; called by muse, mutect2
- CGB5 | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 20/32 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV100031962; called by mutect2, varscan2
- DDX19A | c.1249C>G p.P417A | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.43); PolyPhen benign (0.049); catalogued as COSV100156181; called by muse, mutect2, varscan2
- DGKG | c.754A>G p.T252A | Missense Mutation (SNP) | VAF 28/140 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); catalogued as COSV53962288; called by muse, mutect2, varscan2
- DNAH1 | c.10396G>A p.V3466M | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs542699983, COSV70226988, COSV70238632; called by muse, mutect2, varscan2
- DNAH8 | c.12267T>G p.I4089M | Missense Mutation (SNP) | VAF 81/129 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV59430351; called by muse, mutect2, varscan2
- DNAJC5G | c.319C>T p.H107Y | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as COSV56079580; called by muse, mutect2, varscan2
- DSCAM | c.347T>C p.V116A | Missense Mutation (SNP) | VAF 7/122 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV68629098; called by muse, mutect2
- ECM1 | c.435G>A p.W145* | Nonsense Mutation (SNP) | VAF 59/365 reads (16%) | catalogued as COSV60872032; called by muse, mutect2, varscan2
- ECM1 | c.622G>A p.E208K | Missense Mutation (SNP) | VAF 89/526 reads (17%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.948); catalogued as rs587674518, COSV60872074; called by muse, varscan2
- ERGIC1 | c.29T>G p.I10S | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV67126625; called by muse, mutect2, varscan2
- F10 | c.203G>A p.R68H | Missense Mutation (SNP) | VAF 37/118 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.563); catalogued as rs776339896, COSV65020940; called by muse, mutect2, varscan2
- FCN1 | c.897C>A p.S299R | Missense Mutation (SNP) | VAF 44/122 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as COSV65662033; called by muse, mutect2, varscan2
- FRG2B | c.63G>T p.Q21H | Missense Mutation (SNP) | VAF 13/184 reads (7%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.977); catalogued as COSV101423499, COSV101423536; called by muse, mutect2
- GALNT17 | c.960C>A p.I320= | Splice Region (SNP) | VAF 4/34 reads (12%) | catalogued as COSV100352575, COSV61192457; called by muse, mutect2
- GCN1 | c.7081C>T p.R2361W | Missense Mutation (SNP) | VAF 55/106 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762984260, COSV56104775; called by muse, mutect2, varscan2
- GDF7 | c.1024G>A p.G342R | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.699); catalogued as rs765086458, COSV55347220; called by muse, mutect2
- GIMAP6 | c.836C>T p.S279F | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.722); catalogued as COSV61032693; called by muse, mutect2
- GPHN | c.1732G>A p.E578K (on ENST00000315266 / NM_001377519.1; = p.E611K on NM_020806.5) | Missense Mutation (SNP) | VAF 46/91 reads (51%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.893); catalogued as rs1060499577, COSV59474444; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HEPH | c.2802G>C p.W934C (on ENST00000343002; = p.W667C on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100294843, COSV57960267; called by muse, mutect2, varscan2
- INVS | c.329A>G p.K110R | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.705); catalogued as rs867086899, COSV52438934; called by muse, mutect2, varscan2
- ITPR3 | c.2212C>T p.R738C | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs780991974, COSV65406531; called by muse, mutect2, varscan2
- KCNJ4 | c.484G>A p.V162I | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.024); catalogued as rs1475409490, COSV57856227; called by muse, mutect2, varscan2
- KRTAP4-2 | c.230G>A p.R77H | Missense Mutation (SNP) | VAF 74/147 reads (50%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as rs771456494, COSV66658150; called by muse, mutect2, varscan2
- MRTO4 | c.196T>A p.F66I | Missense Mutation (SNP) | VAF 132/238 reads (55%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.919); catalogued as COSV57673203; called by muse, mutect2, varscan2
- MTRF1L | c.943-2A>G p.X315_splice | Splice Site (SNP) | VAF 19/90 reads (21%) | catalogued as COSV100922423; called by muse, mutect2, varscan2
- NBAS | c.2021T>C p.L674S | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV55714612; called by muse, mutect2, varscan2
- NCF1 | c.634C>A p.P212T | Missense Mutation (SNP) | VAF 29/55 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56875969; called by muse, mutect2, varscan2
- NDST3 | c.366C>G p.D122E | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.02); catalogued as COSV56614111; called by muse, mutect2, varscan2
- NEUROD6 | c.248del p.K83Rfs*35 | Frame Shift Del (DEL) | VAF 26/232 reads (11%) | catalogued as rs752284115; called by mutect2, varscan2
- NSUN2 | c.677A>G p.H226R | Missense Mutation (SNP) | VAF 28/123 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52952830; called by muse, mutect2, varscan2
- OAZ1 | c.436G>A p.G146S | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.836); catalogued as rs770513984, COSV59233917; called by muse, mutect2, varscan2
- PCLO | c.15321G>A p.M5107I | Missense Mutation (SNP) | VAF 56/89 reads (63%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.487); catalogued as COSV61612474, COSV61623605; called by muse, mutect2, varscan2
- PDP2 | c.1430A>G p.H477R | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV61240184; called by muse, mutect2, varscan2
- PGBD4 | c.189C>G p.S63R | Missense Mutation (SNP) | VAF 44/64 reads (69%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.029); catalogued as COSV56626677; called by muse, mutect2, varscan2
- PKHD1L1 | c.3524T>C p.L1175S | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.289); catalogued as COSV65738898; called by muse, mutect2, varscan2
- PKIA | c.136G>C p.D46H | Missense Mutation (SNP) | VAF 14/262 reads (5%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.975); catalogued as COSV61913609; called by muse, mutect2
- PPIE | c.259A>G p.I87V | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as COSV60970936; called by muse, mutect2
- QSOX1 | c.1047C>G p.N349K | Missense Mutation (SNP) | VAF 72/91 reads (79%) | SIFT deleterious (0.02); PolyPhen benign (0.225); catalogued as COSV62579768; called by muse, mutect2, varscan2
- RBMXL1 | c.809G>A p.R270H | Missense Mutation (SNP) | VAF 52/201 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs1254010682, COSV53099088; called by muse, varscan2
- RDX | c.1253C>T p.A418V | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.075); catalogued as rs200525150, COSV58192286; called by muse, mutect2, varscan2
- SCARF1 | c.1346G>A p.R449Q | Missense Mutation (SNP) | VAF 12/17 reads (71%) | SIFT tolerated (0.26); PolyPhen benign (0.009); catalogued as rs1347567281, COSV53957726, COSV99557232; called by muse, mutect2, varscan2
- SLC30A8 | c.958G>T p.A320S | Missense Mutation (SNP) | VAF 39/207 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV69968561; called by muse, varscan2
- SLCO4C1 | c.2044T>G p.F682V | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as COSV60513404; called by muse, mutect2
- SMARCAL1 | c.932C>A p.S311* | Nonsense Mutation (SNP) | VAF 17/43 reads (40%) | catalogued as COSV61920177; called by muse, mutect2, varscan2
- SPOCK1 | c.626G>A p.R209Q | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs750490230, COSV56439386; called by muse, mutect2, varscan2
- SUPT6H | c.2933C>T p.A978V | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0.25); catalogued as COSV58925208; called by muse, mutect2, varscan2
- TAS2R42 | c.745dup p.S249Ffs*55 | Frame Shift Ins (INS) | VAF 26/80 reads (33%) | catalogued as rs753101364; called by mutect2, varscan2
- TNIP3 | c.494C>T p.A165V | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as rs1345798749, COSV50246106, COSV50254706; called by muse, mutect2, varscan2
- TTN | c.91268C>G p.T30423S (on ENST00000591111; = p.T22999S on NM_003319.4) | Missense Mutation (SNP) | VAF 39/98 reads (40%) | PolyPhen probably damaging (0.994); catalogued as COSV59920037; called by muse, mutect2, varscan2
- UBXN2B | c.871C>G p.P291A | Missense Mutation (SNP) | VAF 30/185 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV68308774; called by muse, mutect2, varscan2
- VEGFC | c.88G>A p.A30T | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.103); catalogued as COSV54594758; called by muse, mutect2, varscan2
- ZCCHC14 | c.1993G>A p.V665M (on ENST00000268616; = p.V802M on NM_015144.3) | Missense Mutation (SNP) | VAF 74/124 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51884520; called by muse, mutect2, varscan2
- ZNF229 | c.1476C>G p.D492E | Missense Mutation (SNP) | VAF 16/145 reads (11%) | SIFT tolerated (1); PolyPhen probably damaging (0.992); catalogued as COSV52160232; called by muse, mutect2, varscan2
- ZNF33B | c.77G>C p.W26S | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63942000; called by muse, mutect2, varscan2
- ZNF611 | c.1672A>G p.R558G | Missense Mutation (SNP) | VAF 49/274 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.908); catalogued as COSV60539743; called by muse, mutect2, varscan2
- ANKAR | c.2247_2255del p.N749_L751del | In Frame Del (DEL) | VAF 13/23 reads (57%) | called by mutect2, pindel, varscan2
- FRG2C | c.63G>T p.Q21H | Missense Mutation (SNP) | VAF 30/238 reads (13%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.977); called by muse, mutect2
- TMEM92 | c.457_458dup p.I154Afs*71 | Frame Shift Ins (INS) | VAF 72/169 reads (43%) | called by mutect2, pindel, varscan2
- C1QTNF2 | c.354C>T p.G118= (on ENST00000393975; = p.G73= on NM_031908.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/18 reads (56%) | catalogued as rs374059200; called by muse, mutect2, varscan2
- COL6A3 | c.243C>G p.V81= | Silent (SNP) | VAF 10/58 reads (17%) | catalogued as COSV55081972; called by muse, mutect2, varscan2
- ECM1 | c.531G>A p.L177= | Silent (SNP) | VAF 82/538 reads (15%) | catalogued as COSV60872062; called by muse, varscan2
- ECM1 | c.1014G>A p.L338= | Silent (SNP) | VAF 31/144 reads (22%) | catalogued as COSV60872086; called by muse, varscan2
- EIF2B1 | c.699C>T p.F233= | Silent (SNP) | VAF 11/114 reads (10%) | catalogued as COSV53015462; called by muse, mutect2
- FMNL1 | c.2076C>A p.L692= | Silent (SNP) | VAF 38/135 reads (28%) | catalogued as COSV58955536, COSV58958183; called by muse, mutect2, varscan2
- GUCA1A | c.312C>T p.N104= | Silent (SNP) | VAF 66/93 reads (71%) | catalogued as rs749013749, CM085455, COSV50003573; called by muse, mutect2, varscan2
- IGSF1 | c.3240C>T p.G1080= | Silent (SNP) | VAF 109/133 reads (82%) | catalogued as rs7879617, COSV63836482; called by muse, mutect2, varscan2
- INSM1 | c.918C>T p.C306= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as rs766555814, COSV59604534; called by muse, mutect2
- NCK2 | c.267G>A p.A89= | Silent (SNP) | VAF 72/101 reads (71%) | catalogued as COSV51889133; called by muse, mutect2, varscan2
- OR2AG2 | c.864C>T p.L288= | Silent (SNP) | VAF 31/74 reads (42%) | catalogued as COSV58454713; called by muse, mutect2, varscan2
- PLXNB3 | c.4080C>T p.D1360= | Silent (SNP) | VAF 37/44 reads (84%) | catalogued as rs781989622, COSV62795301; called by muse, mutect2, varscan2
- RP1L1 | c.729G>A p.G243= | Silent (SNP) | VAF 35/52 reads (67%) | catalogued as COSV61444014; called by muse, mutect2, varscan2
- SIPA1L3 | c.999G>A p.P333= | Silent (SNP) | VAF 6/56 reads (11%) | catalogued as rs149728646; called by muse, mutect2, varscan2
- TOP1MT | c.1287C>T p.N429= | Silent (SNP) | VAF 11/87 reads (13%) | catalogued as rs143974988, COSV61316638; called by muse, mutect2, varscan2
- TRMT10C | c.177A>G p.E59= | Silent (SNP) | VAF 17/208 reads (8%) | catalogued as COSV59305235; called by muse, mutect2
- TRPM3 | c.897C>T p.N299= (on ENST00000357533 / NM_001366142.2; = p.N144= on NM_020952.6) | Silent (SNP) | VAF 35/140 reads (25%) | catalogued as rs201646902, COSV62467895, COSV62468247; called by muse, mutect2, varscan2
- UNG | c.270G>C p.V90= (on ENST00000242576 / NM_080911.3; = p.V81= on NM_003362.4) | Silent (SNP) | VAF 40/80 reads (50%) | catalogued as COSV54356782; called by muse, mutect2, varscan2
- YES1 | c.1272T>C p.N424= | Silent (SNP) | VAF 17/57 reads (30%) | catalogued as COSV58848464; called by muse, mutect2, varscan2
- AP004606.1 | chr11:133532316 A>T | 5'Flank (SNP) | VAF 10/18 reads (56%) | catalogued as COSV73218698; called by muse, mutect2, varscan2
- RPL26P30 | n.594C>T | RNA (SNP) | VAF 84/136 reads (62%) | catalogued as rs371873015; called by muse, mutect2, varscan2
- SEBOX | c.-71G>C | 5'UTR (SNP) | VAF 6/27 reads (22%) | catalogued as COSV52646031; called by mutect2, varscan2
- TRIP12 | c.99-843C>A | Intron (SNP) | VAF 55/86 reads (64%) | catalogued as COSV99389495; called by muse, mutect2, varscan2
